Somatic mutation profile of tumor specimen TCGA-CR-7390-01A (aliquot TCGA-CR-7390-01A-11D-2012-08) from TCGA case TCGA-CR-7390, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 67.3 years (24,575 days).
Specimen TCGA-CR-7390-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c7e975f-029c-4b7b-87a2-cd6f191093d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-7390-10A (Blood Derived Normal), aliquot TCGA-CR-7390-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da4e8ee9-ea10-423e-9c48-c700cd6b4e29

The open-access MAF lists 153 somatic variants for this specimen: 104 protein-altering or splice-affecting, 44 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 44, Nonsense Mutation 9, Frame Shift Del 4, Splice Site 3, Frame Shift Ins 3, Intron 2, 3'UTR 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.1184G>A p.R395H | Missense Mutation (SNP) | VAF 14/126 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs769910087, COSV66557504; ClinVar: uncertain significance; called by muse, mutect2
- RIPPLY2 | c.329C>G p.S110* | Nonsense Mutation (SNP) | VAF 17/73 reads (23%) | hotspot (GDC flag); catalogued as COSV100859440, COSV63746041; called by muse, mutect2, varscan2
- ABL2 | c.3062G>A p.G1021E (on ENST00000502732 / NM_007314.4; = p.G1006E on NM_005158.5) | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.756); catalogued as COSV100772378; called by muse, mutect2
- AMPH | c.301-1G>C p.X101_splice | Splice Site (SNP) | VAF 17/161 reads (11%) | catalogued as COSV100340715; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2102A>T p.D701V | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as COSV99781920; called by muse, mutect2, varscan2
- ANKRD11 | c.4088G>A p.R1363Q | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.289); catalogued as COSV99968176; called by muse, mutect2, varscan2
- AP1G2 | c.1780C>T p.Q594* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as COSV99846051; called by muse, mutect2, varscan2
- ARL6IP1 | c.311G>C p.R104T | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV100435755; called by muse, mutect2
- ARSJ | c.519G>A p.M173I | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.241); catalogued as COSV100192408; called by muse, mutect2, varscan2
- ASCL1 | c.702C>G p.N234K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV99901875; called by muse, mutect2, varscan2
- ATRNL1 | c.3404C>A p.A1135E | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100369190; called by muse, mutect2
- BMPER | c.1559A>T p.D520V | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.925); catalogued as COSV99778789; called by muse, mutect2, varscan2
- CABIN1 | c.5999A>G p.H2000R | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.01); catalogued as rs761710567, COSV99572631; called by muse, mutect2, varscan2
- CD2BP2 | c.613T>G p.L205V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV99976921; called by muse, mutect2, varscan2
- CFAP44 | c.2053-1G>C p.X685_splice | Splice Site (SNP) | VAF 7/70 reads (10%) | catalogued as COSV99868802; called by muse, mutect2, varscan2
- CMKLR1 | c.563C>T p.S188F (on ENST00000312143 / NM_001142344.2; = p.S186F on NM_004072.3) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.043); catalogued as COSV56441569; called by muse, mutect2, varscan2
- COL11A1 | c.1006G>C p.E336Q | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.058); catalogued as COSV100614907, COSV62176520, COSV62184186; called by muse, mutect2, varscan2
- CYFIP2 | c.3484T>A p.Y1162N (on ENST00000616178 / NM_001291722.2; = p.Y1137N on NM_014376.4) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV100555550; called by muse, mutect2, varscan2
- DOCK6 | c.1702C>G p.R568G | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52949095, COSV99370845; called by muse, mutect2
- DOCK7 | c.3212A>G p.N1071S (on ENST00000635253 / NM_001367561.1; = p.N1040S on NM_033407.3) | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs779987031, COSV99222535; called by muse, mutect2, varscan2
- EPHA4 | c.2426G>A p.S809N | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56026438; called by muse, mutect2, varscan2
- EPHA7 | c.1322C>A p.A441E | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as COSV100993188; called by muse, mutect2, varscan2
- FAM13C | c.1341A>T p.E447D | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99512980; called by muse, mutect2, varscan2
- FAT1 | c.12820G>T p.E4274* | Nonsense Mutation (SNP) | VAF 21/34 reads (62%) | catalogued as COSV101498907; called by muse, mutect2, varscan2
- FGFBP3 | c.652G>T p.E218* | Nonsense Mutation (SNP) | VAF 14/85 reads (16%) | catalogued as COSV100284594; called by muse, mutect2, varscan2
- FNBP4 | c.1882G>C p.D628H | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99771383; called by muse, varscan2
- FOS | c.260C>G p.P87R | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100338401; called by muse, mutect2, varscan2
- FOXC2 | c.19G>A p.V7M | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1378523304, COSV100234076; called by muse, mutect2, varscan2
- GALNT3 | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV101204874; called by mutect2, varscan2
- GBA2 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs200824511, COSV62305797; called by muse, mutect2, varscan2
- GOLM1 | c.956A>T p.E319V | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV99974203; called by muse, mutect2, varscan2
- GRIN3A | c.618G>C p.M206I | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0.054); catalogued as COSV100701351; called by muse, mutect2, varscan2
- HDC | c.1915G>A p.V639I | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs773972874, COSV51072354, COSV99983792; called by muse, mutect2, varscan2
- HMCN1 | c.1562C>T p.P521L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750199952, COSV99623606; called by mutect2, varscan2
- IL17RE | c.118C>G p.L40V | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV99924655; called by muse, mutect2, varscan2
- ISLR2 | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1395632632, COSV100679355; called by mutect2, varscan2
- ITFG1 | c.1489C>T p.Q497* | Nonsense Mutation (SNP) | VAF 21/105 reads (20%) | catalogued as COSV100278302; called by muse, mutect2, varscan2
- ITGA2 | c.3039+2T>C p.X1013_splice | Splice Site (SNP) | VAF 21/70 reads (30%) | catalogued as COSV99670094; called by muse, mutect2, varscan2
- ITSN2 | c.4276C>G p.L1426V | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.458); catalogued as COSV61948481; called by muse, mutect2, varscan2
- KPNB1 | c.1192G>C p.E398Q | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.123); catalogued as COSV99267741; called by muse, mutect2, varscan2
- LAMA3 | c.799A>C p.T267P | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100555418; called by muse, mutect2, varscan2
- LRFN5 | c.991G>T p.A331S | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs937390788, COSV99982393; called by muse, mutect2, varscan2
- LRRC31 | c.1109C>T p.S370L | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV99246264; called by muse, mutect2, varscan2
- MAP3K12 | c.1993C>A p.P665T | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.037); catalogued as rs768143658, COSV99912877; called by muse, mutect2, varscan2
- MOB1B | c.298G>T p.G100* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100511413; called by muse, mutect2, varscan2
- MPDZ | c.6103G>A p.D2035N (on ENST00000319217 / NM_001330637.2; = p.D2006N on NM_003829.5) | Missense Mutation (SNP) | VAF 69/163 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745854560, COSV59918224; called by muse, mutect2, varscan2
- MYH7 | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV62520933; called by muse, mutect2, varscan2
- NCOA1 | c.1115C>G p.S372C | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as rs1452103947, COSV99945125; called by muse, mutect2, varscan2
- NEXN | c.1044G>C p.R348S | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV100330964; called by muse, mutect2, varscan2
- NKIRAS2 | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 13/80 reads (16%) | catalogued as COSV100288746; called by muse, mutect2, varscan2
- NLN | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV101114100, COSV101114314; called by muse, mutect2, varscan2
- NOTCH1 | c.3238C>T p.Q1080* | Nonsense Mutation (SNP) | VAF 75/142 reads (53%) | catalogued as COSV53103084; called by muse, mutect2, varscan2
- NXPH1 | c.746A>G p.Y249C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101339550; called by muse, mutect2, varscan2
- OR2T4 | c.150C>G p.F50L | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs1238689934, COSV100822389; called by muse, mutect2, varscan2
- OR6C65 | c.142T>A p.L48M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.547); catalogued as COSV101110165; called by muse, mutect2, varscan2
- PCDHGA10 | c.424C>G p.L142V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.02); catalogued as COSV53927062, COSV53998412, COSV99529682; called by muse, mutect2, varscan2
- PER3 | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.182); catalogued as COSV100728196; called by muse, mutect2, varscan2
- PIWIL3 | c.2179G>C p.G727R | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100177311; called by muse, mutect2, varscan2
- POTED | c.285G>C p.R95S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.075); catalogued as COSV100202972; called by muse, mutect2, varscan2
- PPEF1 | c.140C>G p.S47C | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100583508; called by muse, mutect2, varscan2
- PRDM16 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as COSV99575355; called by muse, mutect2, varscan2
- RABGGTB | c.512T>C p.V171A | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100174901; called by muse, mutect2, varscan2
- RAD52 | c.1151G>T p.G384V | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99942383; called by muse, mutect2, varscan2
- RXFP3 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV100347241; called by muse, mutect2, varscan2
- SBF2 | c.3895T>C p.F1299L | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.017); catalogued as COSV99812935; called by muse, mutect2, varscan2
- SETDB1 | c.2041G>A p.D681N | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99643663; called by muse, mutect2, varscan2
- SLC17A6 | c.1225A>G p.R409G | Missense Mutation (SNP) | VAF 36/218 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV99580628; called by muse, mutect2, varscan2
- SLC4A11 | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1420975859, COSV101195874; called by muse, mutect2, varscan2
- SLC52A2 | c.1141C>G p.L381V | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as COSV100095446; called by muse, mutect2, varscan2
- SLC7A8 | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769308396, COSV100328223, COSV57555802; called by muse, mutect2, varscan2
- SNX16 | c.114T>A p.N38K | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV100629469; called by muse, mutect2, varscan2
- SNX3 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV57779573; called by muse, mutect2
- SON | c.1747G>C p.E583Q | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV99276689; called by muse, mutect2, varscan2
- SPZ1 | c.490C>G p.L164V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.485); catalogued as COSV99698045; called by muse, varscan2
- TLR8 | c.850C>G p.Q284E (on ENST00000218032 / NM_138636.5; = p.Q302E on NM_016610.4) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.575); catalogued as COSV99486743; called by muse, mutect2, varscan2
- TMEM132E | c.2273C>T p.A758V (on ENST00000321639; = p.A848V on NM_001304438.2) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs1013692318, COSV100395903; called by muse, mutect2, varscan2
- TMEM168 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV100454467, COSV57179597; called by muse, mutect2, varscan2
- TMEM183A | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs756406896, COSV65887909; called by muse, mutect2, varscan2
- TNRC6C | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs375547025, COSV100049418; called by muse, mutect2, varscan2
- TP53 | c.318C>G p.S106R | Missense Mutation (SNP) | VAF 44/72 reads (61%) | SIFT tolerated (0.41); PolyPhen benign (0.149); catalogued as rs1555526581, CM013441, COSV52748282, COSV52919256, COSV53146850; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53BP1 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.932); catalogued as rs1177812686, COSV55501014; called by muse, mutect2, varscan2
- TSPAN9 | c.99G>A p.W33* | Nonsense Mutation (SNP) | VAF 40/164 reads (24%) | catalogued as COSV99170816; called by muse, mutect2, varscan2
- UBAP2L | c.2390C>T p.P797L | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55178296; called by muse, mutect2, varscan2
- WBP1 | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 48/215 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753973126, COSV99270244, COSV99270783; called by muse, mutect2, varscan2
- WNK3 | c.4723C>A p.Q1575K | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as COSV100670691, COSV63615321; called by muse, mutect2, varscan2
- YWHAH | c.211A>G p.M71V | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV50708333; called by muse, mutect2, varscan2
- ZBTB24 | c.1249G>T p.D417Y | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV57781951; called by muse, mutect2, varscan2
- ZFYVE9 | c.827A>T p.D276V | Missense Mutation (SNP) | VAF 43/249 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV99819293; called by muse, mutect2, varscan2
- ZNF518A | c.1200A>T p.Q400H | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV60151581; called by muse, mutect2, varscan2
- ZNF536 | c.1873A>G p.N625D | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as COSV100834581; called by muse, mutect2, varscan2
- ZNF667 | c.902G>T p.R301I | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as rs199981689; called by muse, mutect2, varscan2
- ZNF667 | c.657G>C p.M219I | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99410001; called by muse, mutect2, varscan2
- ZNF862 | c.1421C>A p.P474Q | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.708); catalogued as COSV99783160; called by muse, mutect2, varscan2
- ATP11B | c.931dup p.W311Lfs*4 | Frame Shift Ins (INS) | VAF 16/96 reads (17%) | called by mutect2, pindel, varscan2
- CEP164 | c.3097_3103del p.E1033Kfs*9 | Frame Shift Del (DEL) | VAF 16/86 reads (19%) | called by mutect2, pindel, varscan2
- DAB1 | c.1258del p.A421Pfs*80 (on ENST00000371231; = p.A388Pfs*80 on NM_021080.5 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 30/101 reads (30%) | called by mutect2, pindel, varscan2
- DST | c.13470_13485del p.I4490Mfs*11 (on ENST00000361203 / NM_001374722.1; = p.I2078Mfs*11 on NM_015548.5) | Frame Shift Del (DEL) | VAF 17/107 reads (16%) | called by mutect2, pindel
- IGHE | c.310G>T p.V104F | Missense Mutation (SNP) | VAF 82/253 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- MEGF10 | c.443G>A p.C148Y | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MR1 | c.716del p.N239Tfs*63 | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | called by mutect2, pindel, varscan2
- SKP2 | c.197dup p.R67Tfs*10 | Frame Shift Ins (INS) | VAF 5/47 reads (11%) | called by pindel, varscan2
- SLC23A1 | c.745dup p.I249Nfs*47 | Frame Shift Ins (INS) | VAF 5/18 reads (28%) | called by mutect2, pindel, varscan2
- STARD8 | c.1870G>A p.E624K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRBV2 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- ABCC8 | c.3270G>A p.L1090= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs1054629799, COSV100216538; called by muse, mutect2, varscan2
- ABRAXAS1 | c.1081C>A p.R361= | Silent (SNP) | VAF 35/165 reads (21%) | catalogued as COSV55029706, COSV99788370; called by muse, mutect2, varscan2
- ALDH1L1 | c.2232C>T p.T744= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as rs141918591; called by muse, mutect2
- ANKRD11 | c.1833C>T p.F611= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as rs1186854251, COSV56371724; called by muse, mutect2, varscan2
- ARHGAP31 | c.2706G>A p.L902= | Silent (SNP) | VAF 36/184 reads (20%) | catalogued as COSV99956485; called by muse, mutect2, varscan2
- ARHGAP5 | c.1233A>G p.E411= | Silent (SNP) | VAF 42/117 reads (36%) | catalogued as rs1382793410, COSV100564967; called by muse, mutect2, varscan2
- BCHE | c.1236C>T p.N412= | Silent (SNP) | VAF 73/110 reads (66%) | catalogued as COSV100012048; called by muse, mutect2, varscan2
- BPIFB2 | c.525G>C p.L175= | Silent (SNP) | VAF 29/157 reads (18%) | catalogued as COSV99401097; called by muse, mutect2, varscan2
- CPNE2 | c.219C>T p.P73= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as rs138897886; called by muse, mutect2, varscan2
- CUBN | c.9036G>A p.P3012= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as rs576867280, COSV64714490; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EN1 | c.1155C>A p.V385= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV54630291, COSV99726950; called by muse, mutect2, varscan2
- FAM102A | c.369G>A p.E123= | Silent (SNP) | VAF 11/107 reads (10%) | catalogued as COSV100305380; called by muse, mutect2, varscan2
- FCRL1 | c.306G>A p.Q102= | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as COSV63826942; called by muse, mutect2, varscan2
- GGA3 | c.1473C>T p.A491= (on ENST00000537686 / NM_138619.4; = p.A458= on NM_014001.5) | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV99821867; called by muse, mutect2
- GTF2IRD1 | c.2052G>A p.K684= (on ENST00000265755 / NM_016328.3; = p.K669= on NM_005685.4) | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV99733961; called by muse, mutect2, varscan2
- HSPA1L | c.1389G>C p.L463= | Silent (SNP) | VAF 34/134 reads (25%) | catalogued as COSV100989320, COSV100989414; called by muse, mutect2, varscan2
- IDH3B | c.838C>T p.L280= | Silent (SNP) | VAF 19/111 reads (17%) | catalogued as COSV100249917, COSV61391712; called by muse, mutect2, varscan2
- IPO4 | c.1632C>T p.S544= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as rs1195109280; called by muse, mutect2
- ITGA11 | c.1893G>A p.V631= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV100240854, COSV100242167; called by muse, mutect2, varscan2
- KIAA0319 | c.1986C>T p.H662= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs773644570, COSV100985158; called by muse, mutect2, varscan2
- KRT37 | c.546G>A p.A182= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as rs778746683, COSV56657409; called by muse, mutect2, varscan2
- LMAN2L | c.543C>T p.N181= | Silent (SNP) | VAF 19/150 reads (13%) | catalogued as rs944368671, COSV99383035; called by muse, mutect2, varscan2
- LY75 | c.4317C>G p.L1439= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as COSV99715901; called by muse, mutect2, varscan2
- MPO | c.1084C>T p.L362= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as COSV99832195; called by muse, mutect2, varscan2
- NLRP8 | c.2890C>T p.L964= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as rs535321291, COSV52585718; called by muse, mutect2, varscan2
- NPAS4 | c.1818C>T p.P606= | Silent (SNP) | VAF 62/177 reads (35%) | catalogued as rs141846354; called by muse, mutect2, varscan2
- NPTN | c.81C>G p.A27= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV99766246; called by muse, mutect2, varscan2
- OR51L1 | c.396G>A p.L132= | Silent (SNP) | VAF 33/200 reads (17%) | catalogued as COSV100386357; called by muse, mutect2, varscan2
- OR56A4 | c.96C>T p.F32= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV100417440; called by muse, mutect2, varscan2
- PI4K2B | c.693G>A p.K231= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs765084289, COSV53511760, COSV53512954; called by mutect2, varscan2
- RBM15 | c.84G>A p.G28= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100873390; called by muse, mutect2, varscan2
- RBM17 | c.429A>G p.E143= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV101159020; called by muse, mutect2, varscan2
- SCYL1 | c.831C>T p.L277= | Silent (SNP) | VAF 9/93 reads (10%) | catalogued as COSV99533697; called by muse, mutect2, varscan2
- SIPA1L3 | c.2142G>A p.R714= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as COSV99727160; called by muse, mutect2, varscan2
- SLC6A18 | c.234C>T p.I78= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs141321317; called by mutect2, varscan2
- SP4 | c.2208G>A p.G736= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as COSV99753977; called by muse, mutect2
- SRRT | c.2091G>A p.V697= | Silent (SNP) | VAF 31/93 reads (33%) | catalogued as COSV99573698; called by muse, mutect2, varscan2
- SYNPO2L | c.1959A>G p.L653= (on ENST00000394810 / NM_001114133.3; = p.L429= on NM_024875.5) | Silent (SNP) | VAF 36/208 reads (17%) | catalogued as rs766065163, COSV100866301; called by muse, mutect2, varscan2
- TBL2 | c.202C>A p.R68= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as rs145718922, COSV99979456; called by muse, mutect2, varscan2
- TEAD3 | c.993C>T p.V331= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV100132264; called by muse, mutect2, varscan2
- TESK2 | c.162G>A p.T54= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as rs1265936469, COSV59149287; called by muse, mutect2, varscan2
- TTN | c.33546A>C p.P11182= (on ENST00000591111; = p.P10255= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV100592524; called by muse, mutect2, varscan2
- ZIC4 | c.165C>G p.P55= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV101267808; called by muse, mutect2, varscan2
- ZNF43 | c.597G>T p.V199= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100731665; called by muse, mutect2, varscan2
- CD300LD | c.40+102C>T | Intron (SNP) | VAF 24/196 reads (12%) | catalogued as rs746228815, COSV60084066; called by muse, mutect2, varscan2
- GCNT2 | c.925+27386C>T | Intron (SNP) | VAF 25/116 reads (22%) | catalogued as rs748768313, COSV100297003; called by muse, mutect2, varscan2
- GPR68 | c.-14C>T | 5'UTR (SNP) | VAF 5/78 reads (6%) | catalogued as COSV53177526, COSV99473335; called by muse, mutect2
- PRR12 | chr19:49594814 G>A | 5'Flank (SNP) | VAF 6/19 reads (32%) | catalogued as COSV55871776; called by mutect2, varscan2
- TRAC | c.*529C>T | 3'UTR (SNP) | VAF 8/52 reads (15%) | catalogued as rs745570645; called by muse, mutect2, varscan2
